Somatic mutation profile of tumor specimen ef52c640-13a9-4855-9ce2-0be77a (aliquot ef52c640-13a9-4855-9ce2-0be77a_D6_1) from CPTAC case 11BR047, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.1 years (21,595 days).
Specimen ef52c640-13a9-4855-9ce2-0be77a: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8b24350-5bba-48d3-8089-484cc4651193.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0bfd3ae8-d275-4dab-9360-d1df30 (Blood Derived Normal), aliquot 0bfd3ae8-d275-4dab-9360-d1df30_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cabae871-f6ed-4458-a95a-ae801ae96fdd

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 4, Splice Site 2, Intron 2, Frame Shift Del 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 40/198 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATL3 | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1326950681; ClinVar: uncertain significance; called by muse, mutect2
- ATP11A | c.2586G>T p.K862N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52118257; called by muse, mutect2, varscan2
- C1orf198 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs761312491; called by muse, mutect2
- NRXN3 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as COSV73585398; called by muse, mutect2, varscan2
- TAF1L | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 24/249 reads (10%) | catalogued as COSV99645321; called by muse, mutect2, varscan2
- TRIM58 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780979068, COSV100825273, COSV63569231; called by mutect2, varscan2
- TTN | c.36419G>A p.R12140H (on ENST00000591111; = p.R4716H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | PolyPhen benign (0.007); catalogued as rs370878642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFDN | c.1675del p.R559Efs*14 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, varscan2
- AP1G1 | c.2108G>T p.G703V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2
- CCPG1 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CIT | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- EMC3 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FLOT1 | c.475-2A>G p.X159_splice | Splice Site (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- HCLS1 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.104); called by mutect2, varscan2
- HINT2 | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA10 | c.441G>C p.M147I | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); called by mutect2, varscan2
- PCDH15 | c.1875T>G p.I625M | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- RAB3C | c.510del p.F170Lfs*93 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- SVEP1 | c.6220G>A p.D2074N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2
- TSC22D1 | c.3197C>A p.S1066* (on ENST00000458659 / NM_183422.4; = p.S137* on NM_006022.4) | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2
- USP34 | c.9729+1G>T p.X3243_splice | Splice Site (SNP) | VAF 57/204 reads (28%) | called by muse, mutect2, varscan2
- ZNF839 | c.2429C>A p.A810D (on ENST00000558850 / NM_001267827.1; = p.A926D on NM_018335.5) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- DCAF12L1 | c.1065G>A p.S355= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV100948117, COSV64422566; called by muse, mutect2
- MED23 | c.813A>G p.R271= | Silent (SNP) | VAF 67/212 reads (32%) | called by muse, mutect2, varscan2
- RBM4 | c.327C>T p.I109= | Silent (SNP) | VAF 71/204 reads (35%) | catalogued as COSV100029547, COSV59519455; called by muse, mutect2, varscan2
- SPEG | c.8475C>G p.P2825= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs374088448, COSV56669955; called by muse, mutect2, varscan2
- BOD1P2 | n.420C>T | RNA (SNP) | VAF 44/122 reads (36%) | catalogued as rs1000887687; called by mutect2, varscan2
- FGG | c.401+43T>C | Intron (SNP) | VAF 68/264 reads (26%) | called by muse, mutect2, varscan2
- SLC35A3 | c.*421G>A | 3'UTR (SNP) | VAF 14/87 reads (16%) | catalogued as COSV64516297; called by muse, varscan2
- VIPR2 | c.51+351G>C | Intron (SNP) | VAF 32/113 reads (28%) | called by mutect2, varscan2
